Gene-level copy-number profile of tumor specimen TCGA-BR-4368-01A from TCGA case TCGA-BR-4368, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 78.8 years (28,770 days).
Specimen TCGA-BR-4368-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d3f9a93f-fd63-4bc9-91d3-4b09ec28ed29.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-4368-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/57fe03ce-deb4-4ea1-b9d7-834b3c823321

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 235; copy number 2: 59,560; copy number 3: 23; copy number 4: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-4368-01A-01D-1155-01): tumor purity 0.42, ploidy 2.41, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 235. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
